Somatic mutation profile of tumor specimen TCGA-L4-A4E5-01A (aliquot TCGA-L4-A4E5-01A-11D-A24P-08) from TCGA case TCGA-L4-A4E5, project TCGA-LUAD (Lung Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage I; Age at diagnosis: 48.4 years (17,680 days).
Specimen TCGA-L4-A4E5-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 1e496d8c-0ab1-4462-b2e2-a48136ab138e.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-L4-A4E5-10A (Blood Derived Normal), aliquot TCGA-L4-A4E5-10A-01D-A24P-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/84c239c8-71c5-4b89-8522-c9368950e2b1

The open-access MAF lists 370 somatic variants for this specimen: 276 protein-altering or splice-affecting, 88 silent, 6 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 234, Silent 88, Nonsense Mutation 23, Splice Site 9, Frame Shift Del 6, Nonstop Mutation 3, RNA 3, Intron 2, Splice Region 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- RB1 | c.1654C>T p.R552* | Nonsense Mutation (SNP) | VAF 16/29 reads (55%) | hotspot (GDC flag); catalogued as rs121913303, CM961229, COSV57297124; ClinVar: pathogenic; called by muse, mutect2, varscan2
- RHO | c.875C>A p.A292E | Missense Mutation (SNP) | VAF 20/67 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.634); catalogued as rs104893789, CM930664, COSV104407280, COSV99960582; ClinVar: pathogenic; called by mutect2, varscan2
- TP53 | c.455C>T p.P152L | Missense Mutation (SNP) | VAF 18/38 reads (47%) | hotspot (GDC flag); SIFT tolerated (0.08); PolyPhen possibly damaging (0.886); catalogued as rs587782705, CD147772, CM941327, COSV52666949, COSV52773466, COSV53038279; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ABCD1 | c.1603C>T p.P535S | Missense Mutation (SNP) | VAF 24/111 reads (22%) | SIFT tolerated (0.27); PolyPhen benign (0.098); catalogued as rs1185254243, CD078363, COSV99497460; called by muse, mutect2, varscan2
- AC006059.2 | c.58C>T p.P20S | Missense Mutation (SNP) | VAF 24/46 reads (52%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.001); catalogued as COSV100359088; called by muse, mutect2, varscan2
- ACSS3 | c.278C>A p.T93K | Missense Mutation (SNP) | VAF 25/80 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.863); catalogued as COSV99698625; called by muse, mutect2, varscan2
- ADAM15 | c.1708T>G p.S570A | Missense Mutation (SNP) | VAF 35/97 reads (36%) | SIFT tolerated (0.07); PolyPhen benign (0.314); catalogued as COSV99664936; called by muse, mutect2, varscan2
- ADGRA3 | c.2155G>T p.G719W | Missense Mutation (SNP) | VAF 58/139 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99293195; called by muse, mutect2, varscan2
- ADGRB3 | c.974A>G p.H325R | Missense Mutation (SNP) | VAF 10/39 reads (26%) | SIFT tolerated (0.61); PolyPhen benign (0.403); catalogued as rs1286692665, COSV101000371; called by muse, mutect2, varscan2
- ADGRG4 | c.6236G>T p.G2079V | Missense Mutation (SNP) | VAF 48/157 reads (31%) | SIFT tolerated (0.11); PolyPhen benign (0.006); catalogued as COSV99795244; called by muse, mutect2, varscan2
- ADH7 | c.861G>A p.M287I | Missense Mutation (SNP) | VAF 10/30 reads (33%) | SIFT deleterious (0.04); PolyPhen benign (0.074); catalogued as COSV99265190; called by muse, varscan2
- AGL | c.341G>T p.R114L | Missense Mutation (SNP) | VAF 52/210 reads (25%) | SIFT tolerated (0.14); PolyPhen benign (0); catalogued as COSV99649057; called by muse, mutect2, varscan2
- AGMO | c.146C>A p.S49Y | Missense Mutation (SNP) | VAF 46/95 reads (48%) | SIFT tolerated (1); PolyPhen benign (0.042); catalogued as rs769378096, COSV61105387, COSV61106804; called by muse, mutect2, varscan2
- AKR7A3 | c.679A>T p.T227S | Missense Mutation (SNP) | VAF 28/106 reads (26%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100853805; called by muse, mutect2
- AMER3 | c.1238C>A p.P413Q | Missense Mutation (SNP) | VAF 22/57 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV100366408; called by muse, mutect2, varscan2
- AMPD1 | c.2078C>A p.P693H | Missense Mutation (SNP) | VAF 17/44 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.962); catalogued as rs267597931, COSV100815000; called by muse, mutect2, varscan2
- ANTXR1 | c.1435-2A>G p.X479_splice | Splice Site (SNP) | VAF 22/74 reads (30%) | catalogued as COSV100362339; called by muse, mutect2, varscan2
- APOB | c.10146G>T p.E3382D | Missense Mutation (SNP) | VAF 53/167 reads (32%) | SIFT tolerated (0.91); PolyPhen probably damaging (0.998); catalogued as COSV51936120, COSV99265135; called by muse, mutect2, varscan2
- AR | c.356C>A p.P119Q | Missense Mutation (SNP) | VAF 4/13 reads (31%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as COSV101018044; called by muse, mutect2, varscan2
- ARHGAP36 | c.184A>T p.K62* | Nonsense Mutation (SNP) | VAF 55/175 reads (31%) | catalogued as COSV99357587; called by muse, mutect2, varscan2
- ARHGAP36 | c.479G>T p.G160V | Missense Mutation (SNP) | VAF 28/130 reads (22%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.996); catalogued as COSV52263732, COSV99357592; called by muse, mutect2, varscan2
- ARHGEF9 | c.1464G>T p.Q488H | Missense Mutation (SNP) | VAF 5/18 reads (28%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.823); catalogued as COSV99491671; called by muse, mutect2
- ARID1A | c.1369C>T p.Q457* | Nonsense Mutation (SNP) | VAF 63/244 reads (26%) | catalogued as COSV61377464, COSV61391132; called by muse, mutect2, varscan2
- ARID1B | c.4462G>T p.V1488L | Missense Mutation (SNP) | VAF 42/85 reads (49%) | SIFT tolerated, low confidence (0.7); PolyPhen benign (0.071); catalogued as rs768210321, COSV99268671; called by muse, mutect2, varscan2
- ARMC5 | c.93G>T p.K31N | Missense Mutation (SNP) | VAF 5/25 reads (20%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.924); catalogued as rs1384598078, COSV99192453; called by muse, mutect2
- ASXL3 | c.4324G>C p.G1442R | Missense Mutation (SNP) | VAF 47/119 reads (39%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.669); catalogued as COSV99324544; called by muse, mutect2, varscan2
- ASXL3 | c.5399C>A p.P1800H | Missense Mutation (SNP) | VAF 57/106 reads (54%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.125); catalogued as COSV99324548; called by muse, mutect2, varscan2
- ATF7IP | c.2344C>T p.P782S | Missense Mutation (SNP) | VAF 38/100 reads (38%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.999); catalogued as rs1194368423, COSV99661542; called by muse, mutect2, varscan2
- ATP7A | c.1087C>A p.L363I | Missense Mutation (SNP) | VAF 87/296 reads (29%) | SIFT tolerated (0.34); PolyPhen benign (0.036); catalogued as COSV100430652; called by muse, mutect2, varscan2
- ATXN7L2 | c.193G>T p.D65Y | Missense Mutation (SNP) | VAF 20/58 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100881326; called by muse, mutect2, varscan2
- AXDND1 | c.429G>C p.K143N | Missense Mutation (SNP) | VAF 15/65 reads (23%) | SIFT tolerated (0.65); PolyPhen benign (0); catalogued as COSV100858336; called by muse, mutect2, varscan2
- BACH2 | c.910G>T p.A304S | Missense Mutation (SNP) | VAF 20/38 reads (53%) | SIFT tolerated (0.63); PolyPhen benign (0.003); catalogued as COSV99998981; called by muse, mutect2, varscan2
- BCHE | c.427G>T p.G143C | Missense Mutation (SNP) | VAF 20/89 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100012403; called by muse, mutect2, varscan2
- BCORL1 | c.5102G>T p.G1701V | Missense Mutation (SNP) | VAF 17/49 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99499216; called by muse, mutect2, varscan2
- BMS1 | c.176+1G>T p.X59_splice | Splice Site (SNP) | VAF 27/119 reads (23%) | catalogued as COSV100996666; called by muse, mutect2, varscan2
- C1D | c.403A>G p.N135D | Missense Mutation (SNP) | VAF 12/27 reads (44%) | SIFT tolerated (0.3); PolyPhen benign (0); catalogued as COSV100878196; called by muse, mutect2, varscan2
- CACNA1I | c.919C>G p.R307G | Missense Mutation (SNP) | VAF 15/39 reads (38%) | SIFT tolerated (0.18); PolyPhen benign (0.306); catalogued as COSV100359957, COSV60806100, COSV60814328; called by muse, mutect2, varscan2
- CACNA2D1 | c.417G>T p.E139D | Missense Mutation (SNP) | VAF 57/82 reads (70%) | SIFT tolerated (0.22); PolyPhen benign (0.006); catalogued as COSV100666486; called by muse, mutect2, varscan2
- CACNG3 | c.201C>A p.C67* | Nonsense Mutation (SNP) | VAF 27/44 reads (61%) | catalogued as COSV99135912; called by muse, mutect2
- CADM3 | c.514C>T p.L172F (on ENST00000368125 / NM_001127173.3; = p.L206F on NM_021189.5) | Missense Mutation (SNP) | VAF 13/53 reads (25%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.969); catalogued as COSV100930314; called by muse, mutect2, varscan2
- CAGE1 | c.1823A>T p.K608I (on ENST00000512086; = p.K472I on NM_205864.3) | Missense Mutation (SNP) | VAF 15/36 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.632); catalogued as COSV99699592; called by muse, mutect2, varscan2
- CARD10 | c.372C>T p.L124= | Splice Region (SNP) | VAF 8/19 reads (42%) | catalogued as rs924356731, COSV52655082, COSV99324865; called by muse, mutect2
- CARD11 | c.163C>T p.Q55* | Nonsense Mutation (SNP) | VAF 107/181 reads (59%) | catalogued as COSV100712230; called by muse, mutect2, varscan2
- CARMIL1 | c.1852G>T p.D618Y | Missense Mutation (SNP) | VAF 23/58 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100277539; called by muse, mutect2, varscan2
- CARMIL1 | c.2469G>T p.L823F | Missense Mutation (SNP) | VAF 39/94 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100277543; called by muse, mutect2, varscan2
- CCDC171 | c.1267G>T p.E423* | Nonsense Mutation (SNP) | VAF 35/125 reads (28%) | catalogued as COSV52640010; called by muse, mutect2, varscan2
- CCDC91 | c.142G>T p.E48* | Nonsense Mutation (SNP) | VAF 67/249 reads (27%) | catalogued as COSV100081666; called by muse, mutect2, varscan2
- CD1E | c.718G>T p.V240L | Missense Mutation (SNP) | VAF 49/85 reads (58%) | SIFT deleterious (0); PolyPhen benign (0.113); catalogued as COSV63770238, COSV63773549; called by muse, mutect2, varscan2
- CDH18 | c.1313G>T p.G438V | Missense Mutation (SNP) | VAF 18/134 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99933993; called by muse, mutect2, varscan2
- CDH23 | c.6457C>A p.P2153T | Missense Mutation (SNP) | VAF 21/68 reads (31%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.841); catalogued as COSV56473973, COSV99820428; called by muse, mutect2, varscan2
- CEACAM21 | c.614G>T p.R205M | Missense Mutation (SNP) | VAF 4/13 reads (31%) | SIFT deleterious (0.02); PolyPhen benign (0.084); catalogued as COSV99494454; called by muse, mutect2, varscan2
- CEP78 | c.1258G>T p.G420C (on ENST00000424347 / NM_001349840.2; = p.G421C on NM_032171.3) | Missense Mutation (SNP) | VAF 22/58 reads (38%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.533); catalogued as COSV99450284; called by muse, mutect2, varscan2
- CHM | c.1135G>T p.G379C | Missense Mutation (SNP) | VAF 22/62 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100753195; called by muse, mutect2, varscan2
- CHODL | c.166G>A p.E56K | Missense Mutation (SNP) | VAF 22/62 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1346283320, COSV54732565; called by muse, mutect2, varscan2
- CHRNA7 | c.994A>T p.R332* | Nonsense Mutation (SNP) | VAF 11/42 reads (26%) | catalogued as COSV100181110; called by mutect2, varscan2
- CMTR2 | c.2155C>T p.Q719* | Nonsense Mutation (SNP) | VAF 22/42 reads (52%) | catalogued as COSV100579104; called by muse, mutect2, varscan2
- CNTFR | c.504C>A p.Y168* | Nonsense Mutation (SNP) | VAF 29/68 reads (43%) | catalogued as COSV100667526; called by muse, mutect2, varscan2
- COL1A2 | c.3750G>T p.M1250I | Missense Mutation (SNP) | VAF 45/56 reads (80%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.76); catalogued as COSV51962237; called by muse, mutect2, varscan2
- COL5A2 | c.182T>C p.I61T | Missense Mutation (SNP) | VAF 29/50 reads (58%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.991); catalogued as COSV100880192; called by muse, mutect2, varscan2
- CPN2 | c.701C>G p.P234R | Missense Mutation (SNP) | VAF 19/45 reads (42%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.798); catalogued as rs199990965, COSV100103034; called by muse, mutect2, varscan2
- CPNE2 | c.447G>T p.Q149H | Missense Mutation (SNP) | VAF 6/12 reads (50%) | SIFT deleterious (0); PolyPhen benign (0.142); catalogued as COSV99321382; called by muse, mutect2, varscan2
- CPSF1 | c.854C>T p.S285L | Missense Mutation (SNP) | VAF 12/39 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.701); catalogued as COSV100574080; called by muse, mutect2, varscan2
- CREBRF | c.1608-2A>G p.X536_splice | Splice Site (SNP) | VAF 43/70 reads (61%) | catalogued as COSV99755704; called by muse, mutect2, varscan2
- CSMD1 | c.4987G>C p.V1663L (on ENST00000520002; = p.V1662L on NM_033225.6) | Missense Mutation (SNP) | VAF 5/10 reads (50%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.989); catalogued as COSV100146860; called by muse, varscan2
- CSMD2 | c.4210G>A p.G1404S | Missense Mutation (SNP) | VAF 21/94 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.918); catalogued as rs200976511, COSV53914025; called by muse, mutect2, varscan2
- DAP | c.182G>T p.G61V | Missense Mutation (SNP) | VAF 22/198 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.767); catalogued as COSV99136302; called by muse, mutect2, varscan2
- DCAF4L2 | c.404T>C p.L135P | Missense Mutation (SNP) | VAF 31/121 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.961); catalogued as COSV100150574, COSV100150783; called by muse, mutect2, varscan2
- DDX11 | c.298G>A p.G100R | Missense Mutation (SNP) | VAF 43/104 reads (41%) | SIFT tolerated (0.35); PolyPhen benign (0); catalogued as COSV99299475; called by muse, mutect2, varscan2
- DENND2A | c.998A>T p.K333M | Missense Mutation (SNP) | VAF 49/71 reads (69%) | SIFT deleterious (0); PolyPhen probably damaging (0.945); catalogued as COSV99325997; called by muse, mutect2, varscan2
- DMRTA2 | c.577T>A p.F193I | Missense Mutation (SNP) | VAF 4/11 reads (36%) | SIFT deleterious (0.03); PolyPhen benign (0.444); catalogued as COSV101288870; called by muse, mutect2
- DOCK2 | c.5181T>A p.H1727Q | Missense Mutation (SNP) | VAF 44/75 reads (59%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as COSV99911695; called by muse, varscan2
- DOK6 | c.391G>T p.V131L | Missense Mutation (SNP) | VAF 13/45 reads (29%) | SIFT tolerated (0.18); PolyPhen benign (0.222); catalogued as COSV66931931; called by muse, mutect2, varscan2
- DPY19L2 | c.1289G>T p.G430V | Missense Mutation (SNP) | VAF 29/85 reads (34%) | SIFT tolerated (0.09); PolyPhen benign (0.199); catalogued as COSV100116682; called by muse, mutect2, varscan2
- DPYS | c.671C>A p.A224E | Missense Mutation (SNP) | VAF 13/41 reads (32%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100679537, COSV60906411; called by muse, mutect2, varscan2
- DRD3 | c.800C>A p.P267Q | Missense Mutation (SNP) | VAF 54/143 reads (38%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.721); catalogued as COSV99879364; called by muse, mutect2, varscan2
- DSCAM | c.2995C>A p.Q999K | Missense Mutation (SNP) | VAF 25/67 reads (37%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.555); catalogued as COSV101259817; called by muse, mutect2, varscan2
- DST | c.13843G>A p.D4615N (on ENST00000361203 / NM_001374722.1; = p.D2203N on NM_015548.5) | Missense Mutation (SNP) | VAF 12/49 reads (24%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.836); catalogued as COSV99754626; called by muse, mutect2, varscan2
- DUSP10 | c.1075C>T p.P359S | Missense Mutation (SNP) | VAF 61/191 reads (32%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.897); catalogued as COSV100100373; called by muse, mutect2, varscan2
- ECPAS | c.1805G>T p.G602V | Missense Mutation (SNP) | VAF 33/125 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV99398040; called by muse, mutect2, varscan2
- EFCAB3 | c.271G>T p.E91* | Nonsense Mutation (SNP) | VAF 39/150 reads (26%) | catalogued as COSV100540153, COSV59502266; called by muse, mutect2, varscan2
- ENPP2 | c.1981C>A p.P661T (on ENST00000075322 / NM_001040092.3; = p.P713T on NM_006209.5) | Missense Mutation (SNP) | VAF 35/128 reads (27%) | SIFT tolerated (0.38); PolyPhen benign (0.112); catalogued as COSV99308071; called by muse, mutect2, varscan2
- FAM135B | c.1425A>C p.E475D | Missense Mutation (SNP) | VAF 24/80 reads (30%) | SIFT tolerated (0.15); PolyPhen benign (0); catalogued as COSV99417889, COSV99427864; called by muse, mutect2, varscan2
- FAM83B | c.626C>G p.T209R | Missense Mutation (SNP) | VAF 13/65 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100174105, COSV100174336; called by muse, mutect2, varscan2
- FBXL7 | c.172C>A p.L58M | Missense Mutation (SNP) | VAF 34/209 reads (16%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.99); catalogued as COSV100309599; called by muse, mutect2, varscan2
- FGF23 | c.329C>A p.P110Q | Missense Mutation (SNP) | VAF 27/101 reads (27%) | SIFT tolerated (0.67); PolyPhen benign (0.115); catalogued as rs773591533, COSV52975735, COSV99426376; called by muse, mutect2, varscan2
- FLG | c.6833G>T p.G2278V | Missense Mutation (SNP) | VAF 242/636 reads (38%) | SIFT tolerated (0.23); PolyPhen benign (0.003); catalogued as COSV100911478; called by muse, mutect2, varscan2
- FMR1 | c.112C>A p.P38T | Missense Mutation (SNP) | VAF 25/101 reads (25%) | SIFT deleterious (0); PolyPhen benign (0.123); catalogued as COSV54425453, COSV99503189; called by muse, mutect2, varscan2
- FOXJ3 | c.1868A>T p.*623Lext*10 | Nonstop Mutation (SNP) | VAF 33/127 reads (26%) | catalogued as COSV100691678; called by muse, mutect2, varscan2
- FPR3 | c.387T>A p.H129Q | Missense Mutation (SNP) | VAF 29/67 reads (43%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.944); catalogued as COSV100200685; called by muse, mutect2, varscan2
- FZD8 | c.1514T>C p.V505A | Missense Mutation (SNP) | VAF 6/46 reads (13%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.679); catalogued as COSV101020218; called by muse, varscan2
- G6PC2 | c.802G>T p.G268C | Missense Mutation (SNP) | VAF 21/57 reads (37%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV99960729; called by muse, mutect2, varscan2
- GALR1 | c.1019C>T p.T340I | Missense Mutation (SNP) | VAF 24/100 reads (24%) | SIFT deleterious (0.05); PolyPhen benign (0.216); catalogued as COSV100231785; called by muse, mutect2, varscan2
- GBP6 | c.1039G>A p.D347N | Missense Mutation (SNP) | VAF 27/79 reads (34%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.978); catalogued as rs377263707; called by muse, mutect2, varscan2
- GCK | c.300C>A p.S100R | Missense Mutation (SNP) | VAF 95/192 reads (49%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.521); catalogued as COSV100596239; called by muse, mutect2, varscan2
- GIPC1 | c.476G>C p.R159P | Missense Mutation (SNP) | VAF 20/37 reads (54%) | SIFT deleterious (0); PolyPhen possibly damaging (0.894); catalogued as COSV100600057, COSV61774660; called by muse, mutect2, varscan2
- GLDC | c.470G>T p.W157L | Missense Mutation (SNP) | VAF 22/100 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100394032; called by muse, mutect2, varscan2
- GLI2 | c.1906C>A p.L636M (on ENST00000361492 / NM_001374353.1; = p.L653M on NM_005270.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 7/25 reads (28%) | SIFT tolerated (0.73); PolyPhen benign (0.097); catalogued as COSV100082967; called by muse, mutect2, varscan2
- GPC4 | c.188G>T p.G63V | Missense Mutation (SNP) | VAF 21/77 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.876); catalogued as COSV100895459; called by muse, mutect2, varscan2
- GPR119 | c.526C>A p.P176T | Missense Mutation (SNP) | VAF 21/82 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52275985, COSV99358606; called by muse, mutect2, varscan2
- GPR176 | c.1090C>A p.R364S | Missense Mutation (SNP) | VAF 46/92 reads (50%) | SIFT deleterious (0); PolyPhen possibly damaging (0.649); catalogued as COSV100137143, COSV54443199; called by muse, mutect2, varscan2
- GPRASP2 | c.1228G>C p.E410Q | Missense Mutation (SNP) | VAF 28/124 reads (23%) | SIFT tolerated (0.36); PolyPhen benign (0.039); catalogued as COSV59990623; called by muse, mutect2, varscan2
- GREB1 | c.5819C>A p.P1940Q | Missense Mutation (SNP) | VAF 41/127 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV52181424, COSV99302778; called by muse, mutect2, varscan2
- GRIN2A | c.1850T>G p.V617G | Missense Mutation (SNP) | VAF 24/50 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100409447; called by muse, mutect2, varscan2
- HCAR2 | c.932G>T p.R311L | Missense Mutation (SNP) | VAF 18/89 reads (20%) | SIFT tolerated (0.46); PolyPhen benign (0.117); catalogued as COSV100186486, COSV61024827; called by muse, mutect2, varscan2
- HCAR3 | c.932G>T p.R311L | Missense Mutation (SNP) | VAF 5/43 reads (12%) | SIFT tolerated (0.25); PolyPhen benign (0.117); catalogued as COSV100811570, COSV63674086; called by muse, mutect2, varscan2
- HELZ2 | c.784G>T p.V262L | Missense Mutation (SNP) | VAF 8/31 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.577); catalogued as COSV100915546; called by muse, mutect2, varscan2
- HHIPL2 | c.1538A>G p.N513S | Missense Mutation (SNP) | VAF 16/68 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); catalogued as rs1422463688, COSV100596794; called by muse, mutect2, varscan2
- HLX | c.1057G>T p.G353C | Missense Mutation (SNP) | VAF 10/34 reads (29%) | SIFT deleterious (0.01); PolyPhen benign (0.41); catalogued as COSV100854523; called by muse, mutect2, varscan2
- HRNR | c.8102C>A p.S2701* | Nonsense Mutation (SNP) | VAF 34/182 reads (19%) | catalogued as COSV100913368; called by muse, mutect2, varscan2
- HUNK | c.643G>T p.G215C | Missense Mutation (SNP) | VAF 35/129 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as COSV54224197; called by muse, mutect2, varscan2
- IGSF1 | c.333G>T p.E111D | Missense Mutation (SNP) | VAF 34/112 reads (30%) | SIFT tolerated (0.45); PolyPhen probably damaging (0.987); catalogued as COSV100812043; called by muse, mutect2, varscan2
- IL18RAP | c.1225G>A p.D409N | Missense Mutation (SNP) | VAF 23/74 reads (31%) | SIFT deleterious (0.02); PolyPhen benign (0.412); catalogued as COSV51825636, COSV99961916; called by muse, mutect2, varscan2
- IL36RN | c.211G>A p.G71R | Missense Mutation (SNP) | VAF 12/55 reads (22%) | SIFT tolerated (0.09); PolyPhen probably damaging (1); catalogued as COSV100697251; called by muse, mutect2, varscan2
- INPP1 | c.368G>C p.R123T | Missense Mutation (SNP) | VAF 25/68 reads (37%) | SIFT tolerated (0.15); PolyPhen benign (0.009); catalogued as rs531380132, COSV100487179; called by muse, mutect2, varscan2
- ITGAD | c.2483G>A p.R828Q | Missense Mutation (SNP) | VAF 21/65 reads (32%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.903); catalogued as rs992896693, COSV101210429, COSV66757742; called by muse, mutect2, varscan2
- ITGAX | c.2270C>A p.A757D | Missense Mutation (SNP) | VAF 17/45 reads (38%) | SIFT deleterious (0.01); PolyPhen benign (0.031); catalogued as COSV99191633; called by muse, mutect2, varscan2
- KALRN | c.3493G>T p.E1165* | Nonsense Mutation (SNP) | VAF 50/149 reads (34%) | catalogued as COSV99563634; called by muse, mutect2, varscan2
- KBTBD3 | c.13A>G p.M5V | Missense Mutation (SNP) | VAF 15/38 reads (39%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.373); catalogued as rs1447204591, COSV101595684; called by muse, mutect2, varscan2
- KCNA1 | c.655G>T p.D219Y | Missense Mutation (SNP) | VAF 21/77 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.477); catalogued as COSV101230204, COSV66838667; called by muse, mutect2, varscan2
- KCNA5 | c.1306C>A p.L436M | Missense Mutation (SNP) | VAF 19/73 reads (26%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.951); catalogued as COSV99363831; called by muse, mutect2, varscan2
- KCNG1 | c.1394G>T p.R465L | Missense Mutation (SNP) | VAF 29/79 reads (37%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.954); catalogued as COSV100857071; called by muse, mutect2, varscan2
- KCNIP3 | c.266C>G p.T89S | Missense Mutation (SNP) | VAF 7/35 reads (20%) | SIFT tolerated (0.33); PolyPhen benign (0.01); catalogued as COSV54668530; called by muse, mutect2, varscan2
- KCNJ3 | c.39G>T p.Q13H | Missense Mutation (SNP) | VAF 22/86 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); catalogued as COSV99715544, COSV99715651; called by muse, mutect2, varscan2
- KCNQ2 | c.412G>T p.G138C | Missense Mutation (SNP) | VAF 23/82 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100610065; called by muse, mutect2, varscan2
- KCNT2 | c.2972A>T p.H991L | Missense Mutation (SNP) | VAF 54/84 reads (64%) | SIFT tolerated (0.39); PolyPhen benign (0); catalogued as COSV99653125; called by muse, mutect2, varscan2
- KCTD10 | c.694G>A p.V232I | Missense Mutation (SNP) | VAF 4/68 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.978); catalogued as COSV57326990; called by muse, mutect2
- KHDRBS2 | c.440G>T p.R147L | Missense Mutation (SNP) | VAF 20/85 reads (24%) | SIFT tolerated (0.21); PolyPhen probably damaging (0.987); catalogued as COSV55434666, COSV99832969; called by muse, mutect2, varscan2
- KHNYN | c.323C>T p.S108L | Missense Mutation (SNP) | VAF 27/72 reads (38%) | SIFT deleterious (0); PolyPhen benign (0.05); catalogued as COSV99249625; called by muse, mutect2, varscan2
- KLHL13 | c.1737T>A p.D579E | Missense Mutation (SNP) | VAF 63/207 reads (30%) | SIFT tolerated (1); PolyPhen benign (0.055); catalogued as COSV53254166, COSV99451496; called by muse, mutect2, varscan2
- LAMA2 | c.2936G>A p.C979Y | Missense Mutation (SNP) | VAF 9/31 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV101370368; called by muse, mutect2, varscan2
- LHCGR | c.1712T>C p.M571T | Missense Mutation (SNP) | VAF 33/128 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs1558797615, COSV54303264; called by muse, mutect2, varscan2
- LMAN2L | c.605C>T p.A202V | Missense Mutation (SNP) | VAF 40/98 reads (41%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.816); catalogued as COSV99383288; called by muse, mutect2, varscan2
- LMBRD2 | c.511G>T p.V171L | Missense Mutation (SNP) | VAF 64/109 reads (59%) | SIFT tolerated (0.7); PolyPhen benign (0.167); catalogued as COSV99682778; called by muse, mutect2, varscan2
- LRFN5 | c.1765G>A p.V589M | Missense Mutation (SNP) | VAF 19/88 reads (22%) | SIFT tolerated (0.22); PolyPhen benign (0.042); catalogued as rs772023044, COSV53257915; called by muse, mutect2, varscan2
- LRIT2 | c.221C>A p.S74Y | Missense Mutation (SNP) | VAF 38/104 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.726); catalogued as COSV100928299; called by muse, mutect2, varscan2
- LRP1B | c.12924C>A p.Y4308* | Nonsense Mutation (SNP) | VAF 90/230 reads (39%) | catalogued as COSV101255662, COSV67202851; called by muse, mutect2, varscan2
- LRP1B | c.3073T>A p.C1025S | Missense Mutation (SNP) | VAF 14/59 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV101255664; called by muse, mutect2, varscan2
- LRRC32 | c.1078G>T p.G360C | Missense Mutation (SNP) | VAF 13/36 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.72); catalogued as COSV99476903; called by muse, mutect2, varscan2
- LURAP1 | c.40G>T p.D14Y | Missense Mutation (SNP) | VAF 17/58 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as COSV100915068; called by muse, mutect2, varscan2
- MAD2L1BP | c.563G>T p.R188L | Missense Mutation (SNP) | VAF 9/38 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV100937799; called by muse, mutect2, varscan2
- MAP7D2 | c.1153G>T p.A385S | Missense Mutation (SNP) | VAF 67/126 reads (53%) | SIFT tolerated (0.42); PolyPhen benign (0.168); catalogued as COSV65526046; called by muse, mutect2, varscan2
- MINDY3 | c.692C>T p.S231F | Missense Mutation (SNP) | VAF 26/79 reads (33%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as COSV99510681; called by muse, mutect2, varscan2
- MMP16 | c.446G>T p.R149L | Missense Mutation (SNP) | VAF 25/72 reads (35%) | SIFT tolerated (0.41); PolyPhen benign (0.02); catalogued as COSV54149337; called by muse, mutect2, varscan2
- MMP21 | c.577G>T p.D193Y | Missense Mutation (SNP) | VAF 7/13 reads (54%) | SIFT deleterious (0); PolyPhen benign (0.3); catalogued as COSV100916674; called by muse, mutect2
- MPP2 | c.1730G>T p.*577Lext*12 (on ENST00000461854 / NM_001278372.2; = p.*553Lext*12 on NM_005374.5) | Nonstop Mutation (SNP) | VAF 25/120 reads (21%) | catalogued as COSV99290304; called by muse, mutect2, varscan2
- MTUS2 | c.1351G>T p.D451Y | Missense Mutation (SNP) | VAF 17/40 reads (43%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.562); catalogued as COSV101462172; called by muse, mutect2, varscan2
- MUC16 | c.3830C>A p.S1277Y | Missense Mutation (SNP) | VAF 105/226 reads (46%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.452); catalogued as COSV101199514; called by muse, mutect2, varscan2
- MYEF2 | c.1098G>C p.M366I | Missense Mutation (SNP) | VAF 53/142 reads (37%) | SIFT tolerated (0.24); PolyPhen benign (0); catalogued as COSV99981478; called by muse, mutect2, varscan2
- MYF6 | c.386C>A p.P129H | Missense Mutation (SNP) | VAF 33/83 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57350528, COSV99952734, COSV99952767; called by muse, mutect2, varscan2
- MYH1 | c.5106C>A p.S1702R | Missense Mutation (SNP) | VAF 25/53 reads (47%) | SIFT tolerated (0.08); PolyPhen benign (0.231); catalogued as COSV99875642; called by muse, mutect2, varscan2
- MYH13 | c.44C>A p.P15H | Missense Mutation (SNP) | VAF 4/17 reads (24%) | SIFT deleterious (0.02); PolyPhen benign (0.013); catalogued as COSV99353564; called by muse, mutect2
- NAV3 | c.2735C>A p.S912Y | Missense Mutation (SNP) | VAF 40/119 reads (34%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.687); catalogued as rs747470589, COSV99889733; called by muse, mutect2, varscan2
- NCKAP5L | c.192+1G>T p.X64_splice | Splice Site (SNP) | VAF 15/73 reads (21%) | catalogued as COSV100258673; called by muse, mutect2, varscan2
- NDUFAF2 | c.194G>T p.G65V | Missense Mutation (SNP) | VAF 46/97 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.943); catalogued as COSV99681295; called by muse, mutect2, varscan2
- NEB | c.9653C>T p.T3218I | Missense Mutation (SNP) | VAF 6/19 reads (32%) | SIFT deleterious (0.02); PolyPhen benign (0.012); catalogued as rs1003683269, COSV99420582; called by muse, mutect2, varscan2
- NEFM | c.47G>T p.R16L | Missense Mutation (SNP) | VAF 6/13 reads (46%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as COSV99647141; called by muse, varscan2
- NEU2 | c.946C>A p.P316T | Missense Mutation (SNP) | VAF 31/76 reads (41%) | SIFT tolerated (0.65); PolyPhen possibly damaging (0.506); catalogued as COSV99290531; called by muse, mutect2, varscan2
- NF1 | c.4851A>T p.Q1617H (on ENST00000358273 / NM_001042492.3; = p.Q1596H on NM_000267.3) | Missense Mutation (SNP) | VAF 35/124 reads (28%) | SIFT deleterious (0.01); PolyPhen benign (0.175); catalogued as COSV55987162, COSV99907569; called by muse, mutect2, varscan2
- NFATC1 | c.1381G>A p.V461M | Missense Mutation (SNP) | VAF 16/88 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs1209425007, COSV53697647; called by muse, mutect2, varscan2
- NHS | c.1481G>T p.G494V | Missense Mutation (SNP) | VAF 39/97 reads (40%) | SIFT tolerated (0.24); PolyPhen benign (0.369); catalogued as COSV101196549, COSV66275208; called by muse, mutect2, varscan2
- NID1 | c.1185C>A p.H395Q | Missense Mutation (SNP) | VAF 62/86 reads (72%) | SIFT tolerated (0.25); PolyPhen benign (0.005); catalogued as COSV99937402; called by muse, mutect2, varscan2
- NISCH | c.379G>T p.A127S | Missense Mutation (SNP) | VAF 36/101 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.969); catalogued as COSV100617288, COSV61899772; called by muse, mutect2, varscan2
- NLRP1 | c.2147T>C p.L716P | Missense Mutation (SNP) | VAF 41/131 reads (31%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.979); catalogued as rs201817755; called by muse, mutect2, varscan2
- NOL8 | c.1619G>A p.R540H | Missense Mutation (SNP) | VAF 15/69 reads (22%) | SIFT tolerated (0.56); PolyPhen benign (0); catalogued as rs200196088, COSV100694521; called by muse, mutect2, varscan2
- NPAP1 | c.1711G>T p.V571L | Missense Mutation (SNP) | VAF 48/115 reads (42%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV100275237; called by muse, mutect2, varscan2
- NPTX1 | c.1165G>T p.G389W | Missense Mutation (SNP) | VAF 16/117 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV60775223, COSV60776878; called by muse, mutect2, varscan2
- NUAK1 | c.1929G>T p.M643I | Missense Mutation (SNP) | VAF 33/135 reads (24%) | SIFT tolerated (0.14); PolyPhen benign (0.13); catalogued as COSV99776902; called by muse, mutect2, varscan2
- NXF3 | c.572C>A p.P191H | Missense Mutation (SNP) | VAF 30/103 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101221926; called by muse, mutect2, varscan2
- NXPE1 | c.1285G>T p.D429Y (on ENST00000424269; = p.D287Y on NM_152315.5) | Missense Mutation (SNP) | VAF 43/90 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV99320325; called by muse, mutect2, varscan2
- OBI1 | c.760G>C p.V254L | Missense Mutation (SNP) | VAF 27/62 reads (44%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs758842862, COSV99932422; called by muse, varscan2
- OBSCN | c.11471A>T p.E3824V | Missense Mutation (SNP) | VAF 55/174 reads (32%) | SIFT deleterious (0.05); PolyPhen benign (0.336); catalogued as COSV99476681; called by muse, mutect2, varscan2
- OGDHL | c.382G>T p.G128C | Missense Mutation (SNP) | VAF 16/49 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1373236645, COSV100934276; called by muse, mutect2, varscan2
- OR11H6 | c.273C>A p.Y91* | Nonsense Mutation (SNP) | VAF 25/69 reads (36%) | catalogued as COSV100209795; called by muse, mutect2, varscan2
- OR4C16 | c.826G>C p.G276R | Missense Mutation (SNP) | VAF 24/57 reads (42%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.988); catalogued as COSV100114014; called by muse, mutect2, varscan2
- OR4D11 | c.289T>C p.C97R | Missense Mutation (SNP) | VAF 70/214 reads (33%) | SIFT deleterious (0.01); PolyPhen benign (0.242); catalogued as COSV100506528, COSV100506670; called by muse, mutect2, varscan2
- OR51V1 | c.13G>C p.V5L | Missense Mutation (SNP) | VAF 24/54 reads (44%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100343350; called by muse, mutect2, varscan2
- OR5AP2 | c.440G>T p.C147F | Missense Mutation (SNP) | VAF 27/97 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as COSV100266167; called by muse, mutect2, varscan2
- OR5F1 | c.170C>A p.T57K | Missense Mutation (SNP) | VAF 16/65 reads (25%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.878); catalogued as COSV99558556; called by muse, mutect2, varscan2
- OTUD6B | c.577G>A p.D193N | Missense Mutation (SNP) | VAF 4/14 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.979); catalogued as COSV99575906; called by muse, mutect2
- PAGE4 | c.259C>A p.P87T | Missense Mutation (SNP) | VAF 24/69 reads (35%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.977); catalogued as COSV99489800; called by muse, mutect2, varscan2
- PCDH15 | c.5149C>T p.P1717S | Missense Mutation (SNP) | VAF 5/12 reads (42%) | SIFT tolerated, low confidence (0.14); catalogued as rs897176331, COSV100903865; called by muse, mutect2, varscan2
- PCDHA5 | c.779T>A p.V260D | Missense Mutation (SNP) | VAF 38/72 reads (53%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as COSV100972233; called by muse, mutect2, varscan2
- PCDHGA2 | c.77C>T p.A26V | Missense Mutation (SNP) | VAF 23/54 reads (43%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.022); catalogued as COSV53932454; called by muse, mutect2, varscan2
- PCLO | c.6388G>T p.V2130F | Missense Mutation (SNP) | VAF 45/70 reads (64%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV100431159; called by muse, mutect2, varscan2
- PEAR1 | c.377G>A p.W126* | Nonsense Mutation (SNP) | VAF 18/170 reads (11%) | catalogued as COSV99441225; called by muse, mutect2, varscan2
- PLEKHM1 | c.2912G>A p.G971E | Missense Mutation (SNP) | VAF 12/38 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.961); catalogued as COSV101378716; called by muse, mutect2, varscan2
- PLOD2 | c.1839G>T p.M613I | Missense Mutation (SNP) | VAF 31/93 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.65); catalogued as COSV51463569; called by muse, mutect2, varscan2
- POTEE | c.2659G>T p.D887Y | Missense Mutation (SNP) | VAF 22/223 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.912); catalogued as rs747787553, COSV100387672; called by muse, varscan2
- POTEF | c.2659G>T p.D887Y | Missense Mutation (SNP) | VAF 8/32 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.939); catalogued as COSV100664795; called by muse, mutect2, varscan2
- PRDM9 | c.883-2A>T p.X295_splice | Splice Site (SNP) | VAF 52/161 reads (32%) | catalogued as rs1324310942, COSV99690297; called by muse, mutect2, varscan2
- PRR15L | c.35T>A p.F12Y | Missense Mutation (SNP) | VAF 37/117 reads (32%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.673); catalogued as COSV99846495; called by muse, mutect2, varscan2
- PRSS38 | c.797G>T p.G266V | Missense Mutation (SNP) | VAF 12/44 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100816463; called by muse, mutect2, varscan2
- PSKH1 | c.727G>T p.A243S | Missense Mutation (SNP) | VAF 11/39 reads (28%) | SIFT tolerated (0.32); PolyPhen possibly damaging (0.718); catalogued as rs368564776, COSV52125179; called by muse, mutect2, varscan2
- PTPRD | c.5508A>C p.Q1836H | Missense Mutation (SNP) | VAF 20/71 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV100644371; called by muse, mutect2, varscan2
- PXDNL | c.2881G>T p.A961S | Missense Mutation (SNP) | VAF 5/13 reads (38%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.817); catalogued as COSV100680846, COSV100683167; called by muse, mutect2, varscan2
- RAPGEF6 | c.3613A>T p.T1205S | Missense Mutation (SNP) | VAF 15/28 reads (54%) | SIFT tolerated, low confidence (0.67); PolyPhen benign (0.003); catalogued as COSV99726210; called by muse, mutect2, varscan2
- RASA3 | c.2241G>T p.M747I | Missense Mutation (SNP) | VAF 6/11 reads (55%) | SIFT tolerated (0.09); PolyPhen benign (0.387); catalogued as COSV100480378, COSV100481265; called by muse, mutect2, varscan2
- RASEF | c.584A>T p.Q195L | Missense Mutation (SNP) | VAF 32/95 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.937); catalogued as COSV100906840; called by muse, mutect2, varscan2
- RBM4 | c.1093T>A p.*365Kext*75 | Nonstop Mutation (SNP) | VAF 20/60 reads (33%) | catalogued as COSV100029601; called by muse, mutect2, varscan2
- RBMS1 | c.198C>G p.I66M | Missense Mutation (SNP) | VAF 29/64 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100816812; called by muse, mutect2, varscan2
- RBP2 | c.231C>G p.S77R | Missense Mutation (SNP) | VAF 35/94 reads (37%) | SIFT deleterious (0.01); PolyPhen benign (0.031); catalogued as COSV51672658, COSV99218320; called by muse, mutect2, varscan2
- RBPJL | c.1302C>A p.C434* | Nonsense Mutation (SNP) | VAF 4/8 reads (50%) | catalogued as rs1333952891, COSV100643481, COSV59212787; called by muse, mutect2, varscan2
- RICTOR | c.1400+2T>G p.X467_splice | Splice Site (SNP) | VAF 16/95 reads (17%) | catalogued as COSV99704785; called by muse, mutect2, varscan2
- RYR2 | c.6268C>T p.R2090W | Missense Mutation (SNP) | VAF 8/58 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1284802339, COSV63669937; called by muse, mutect2, varscan2
- SCN8A | c.4290G>T p.E1430D | Missense Mutation (SNP) | VAF 12/37 reads (32%) | SIFT tolerated (0.29); PolyPhen benign (0.007); catalogued as COSV100633692; called by muse, mutect2, varscan2
- SGIP1 | c.1310C>A p.T437N | Missense Mutation (SNP) | VAF 71/255 reads (28%) | SIFT tolerated (0.31); PolyPhen benign (0.026); catalogued as COSV99391232; called by muse, mutect2, varscan2
- SLC26A11 | c.934G>A p.V312M | Missense Mutation (SNP) | VAF 7/18 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs549132744, COSV63279398; called by muse, mutect2, varscan2
- SLC28A3 | c.1315G>A p.G439R | Missense Mutation (SNP) | VAF 14/43 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100883219, COSV100883356; called by muse, mutect2, varscan2
- SLC35G2 | c.382C>T p.R128W | Missense Mutation (SNP) | VAF 62/222 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs570589760, COSV101261948; called by muse, mutect2, varscan2
- SLC7A13 | c.1025T>C p.L342P | Missense Mutation (SNP) | VAF 79/153 reads (52%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.913); catalogued as COSV99878815; called by muse, mutect2, varscan2
- SLC9A6 | c.1676C>A p.T559K | Missense Mutation (SNP) | VAF 14/34 reads (41%) | SIFT tolerated (0.19); PolyPhen benign (0.044); catalogued as COSV100857889; called by muse, mutect2, varscan2
- SLITRK1 | c.1738C>T p.Q580* | Nonsense Mutation (SNP) | VAF 14/24 reads (58%) | catalogued as COSV100999913; called by muse, mutect2, varscan2
- SMARCD2 | c.232C>T p.P78S | Missense Mutation (SNP) | VAF 3/29 reads (10%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.007); catalogued as COSV99856359; called by muse, mutect2
- SMYD2 | c.407C>G p.S136* | Nonsense Mutation (SNP) | VAF 53/79 reads (67%) | catalogued as COSV100873175, COSV65290438; called by muse, mutect2, varscan2
- SNAPC4 | c.3863G>T p.G1288V | Missense Mutation (SNP) | VAF 5/17 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV100047122; called by muse, mutect2
- SNTG1 | c.704C>A p.A235D | Missense Mutation (SNP) | VAF 25/98 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV52449973; called by muse, mutect2, varscan2
- SOX6 | c.1229C>A p.T410N (on ENST00000528429 / NM_001145819.2; = p.T369N on NM_017508.3) | Missense Mutation (SNP) | VAF 22/48 reads (46%) | SIFT tolerated (0.46); PolyPhen benign (0.005); catalogued as COSV100321913; called by muse, mutect2, varscan2
- SOX7 | c.49C>G p.P17A | Missense Mutation (SNP) | VAF 6/16 reads (38%) | SIFT tolerated (0.08); PolyPhen benign (0.001); catalogued as COSV100449034; called by muse, mutect2, varscan2
- SPAG17 | c.3761G>A p.W1254* | Nonsense Mutation (SNP) | VAF 25/92 reads (27%) | catalogued as rs1369550662, COSV100308797; called by muse, mutect2, varscan2
- SPTA1 | c.714G>T p.K238N | Missense Mutation (SNP) | VAF 10/51 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.857); catalogued as rs1014342278, COSV100934768; called by muse, mutect2, varscan2
- SSH3 | c.465-2A>T p.X155_splice | Splice Site (SNP) | VAF 14/54 reads (26%) | catalogued as COSV100354518; called by mutect2, varscan2
- ST6GALNAC3 | c.668T>C p.L223P | Missense Mutation (SNP) | VAF 38/150 reads (25%) | PolyPhen benign (0.426); catalogued as COSV100082749; called by muse, mutect2, varscan2
- STAG2 | c.135A>T p.K45N | Missense Mutation (SNP) | VAF 23/95 reads (24%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.95); catalogued as COSV99493134; called by muse, mutect2, varscan2
- STK33 | c.559-2A>T p.X187_splice | Splice Site (SNP) | VAF 14/32 reads (44%) | catalogued as COSV100173917; called by muse, mutect2, varscan2
- STYXL2 | c.954C>A p.D318E | Missense Mutation (SNP) | VAF 4/12 reads (33%) | SIFT tolerated (0.3); PolyPhen benign (0.021); catalogued as COSV54804754, COSV99609063; called by muse, mutect2
- SYBU | c.304G>T p.G102C (on ENST00000276646 / NM_001099754.2; = p.G101C on NM_017786.6) | Missense Mutation (SNP) | VAF 35/111 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.939); catalogued as COSV99406035; called by muse, mutect2, varscan2
- SYNC | c.1202A>T p.Q401L | Missense Mutation (SNP) | VAF 130/419 reads (31%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.596); catalogued as COSV100995274; called by muse, mutect2, varscan2
- SYNE2 | c.1042G>T p.D348Y | Missense Mutation (SNP) | VAF 26/85 reads (31%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.635); catalogued as COSV100647419; called by muse, mutect2, varscan2
- TAF4 | c.1604A>T p.Q535L | Missense Mutation (SNP) | VAF 53/112 reads (47%) | SIFT tolerated (0.16); PolyPhen benign (0.201); catalogued as COSV99433990; called by muse, mutect2, varscan2
- TDRD3 | c.895G>T p.G299* | Nonsense Mutation (SNP) | VAF 30/85 reads (35%) | catalogued as COSV99540158; called by muse, mutect2, varscan2
- TENM2 | c.751C>A p.P251T (on ENST00000518659 / NM_001122679.2; = p.P60T on NM_001080428.3) | Missense Mutation (SNP) | VAF 13/21 reads (62%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.995); catalogued as COSV101318525; called by muse, mutect2, varscan2
- TENM2 | c.752C>A p.P251H (on ENST00000518659 / NM_001122679.2; = p.P60H on NM_001080428.3) | Missense Mutation (SNP) | VAF 12/19 reads (63%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as COSV101318527; called by muse, mutect2, varscan2
- TENT5C | c.491A>T p.N164I | Missense Mutation (SNP) | VAF 16/101 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV101032915, COSV65617036; called by muse, mutect2
- TET1 | c.820G>A p.G274S | Missense Mutation (SNP) | VAF 36/116 reads (31%) | SIFT tolerated (0.11); PolyPhen benign (0.333); catalogued as COSV101018029; called by muse, mutect2, varscan2
- TGFBI | c.464T>A p.V155E | Missense Mutation (SNP) | VAF 4/15 reads (27%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.678); catalogued as COSV100526438; called by muse, mutect2, varscan2
- TGFBR3 | c.1151C>T p.P384L | Missense Mutation (SNP) | VAF 10/45 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs868246724, COSV99282807; called by muse, mutect2, varscan2
- TIAM1 | c.2284G>A p.E762K | Missense Mutation (SNP) | VAF 23/71 reads (32%) | SIFT tolerated (0.12); PolyPhen benign (0.174); catalogued as rs979201216, COSV99734507; called by muse, mutect2, varscan2
- TIAM1 | c.480G>A p.M160I | Missense Mutation (SNP) | VAF 39/104 reads (38%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0); catalogued as COSV99734509; called by muse, mutect2, varscan2
- TMEM170B | c.336G>T p.W112C | Missense Mutation (SNP) | VAF 40/132 reads (30%) | SIFT deleterious (0); PolyPhen benign (0.251); catalogued as COSV101053257; called by muse, mutect2, varscan2
- TMEM87B | c.1033G>T p.G345C | Missense Mutation (SNP) | VAF 8/32 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.957); catalogued as COSV99314232; called by mutect2, varscan2
- TNFAIP3 | c.2227A>T p.M743L | Missense Mutation (SNP) | VAF 35/67 reads (52%) | SIFT tolerated (0.38); PolyPhen benign (0); catalogued as rs552233795, COSV99396639; called by muse, mutect2, varscan2
- TNK2 | c.1343G>A p.G448D | Missense Mutation (SNP) | VAF 3/36 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV100361215; called by muse, mutect2
- TNR | c.2402C>G p.A801G | Missense Mutation (SNP) | VAF 14/56 reads (25%) | SIFT tolerated (0.35); PolyPhen probably damaging (0.959); catalogued as COSV99689133; called by muse, mutect2, varscan2
- TNS1 | c.887A>C p.E296A | Missense Mutation (SNP) | VAF 18/37 reads (49%) | SIFT deleterious (0); PolyPhen possibly damaging (0.743); catalogued as rs944657074, COSV99410466; called by muse, mutect2, varscan2
- TPTE | c.1423G>A p.D475N (on ENST00000618007 / NM_199261.4; = p.D457N on NM_199259.4) | Missense Mutation (SNP) | VAF 21/150 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs1314927846; called by muse, mutect2, varscan2
- TRIM36 | c.1429G>T p.D477Y | Missense Mutation (SNP) | VAF 25/50 reads (50%) | SIFT tolerated (0.27); PolyPhen possibly damaging (0.696); catalogued as COSV99142339; called by muse, mutect2, varscan2
- TRIOBP | c.256G>A p.G86S | Missense Mutation (SNP) | VAF 8/16 reads (50%) | SIFT tolerated, low confidence (0.56); PolyPhen benign (0.005); catalogued as COSV60378701; called by muse, varscan2
- TRIOBP | c.257G>T p.G86V | Missense Mutation (SNP) | VAF 8/16 reads (50%) | SIFT tolerated, low confidence (0.23); PolyPhen benign (0.003); catalogued as COSV100730813; called by muse, mutect2, varscan2
- TRO | c.3868G>T p.G1290C | Missense Mutation (SNP) | VAF 23/93 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.99); catalogued as COSV99436257; called by muse, mutect2, varscan2
- TTC12 | c.1990G>T p.V664L | Missense Mutation (SNP) | VAF 16/57 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV100133055; called by muse, mutect2, varscan2
- UBR5 | c.6316G>A p.A2106T | Missense Mutation (SNP) | VAF 23/84 reads (27%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.956); catalogued as rs1410980842, COSV55290135; called by muse, mutect2, varscan2
- UGT2B11 | c.428C>A p.S143* | Nonsense Mutation (SNP) | VAF 52/98 reads (53%) | catalogued as COSV101485244; called by muse, mutect2, varscan2
- VSNL1 | c.89G>T p.W30L | Missense Mutation (SNP) | VAF 36/138 reads (26%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.585); catalogued as COSV54598359; called by muse, mutect2, varscan2
- WNK2 | c.998G>T p.G333V | Missense Mutation (SNP) | VAF 47/145 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99941959; called by muse, mutect2, varscan2
- XIRP2 | c.5462C>A p.T1821N (on ENST00000628543; = p.T1996N on NM_152381.6) | Missense Mutation (SNP) | VAF 22/48 reads (46%) | SIFT tolerated (0.2); PolyPhen benign (0.039); catalogued as COSV54728337; called by muse, mutect2, varscan2
- ZFHX4 | c.4192C>A p.R1398S | Missense Mutation (SNP) | VAF 39/72 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV50500968, COSV99258341; called by muse, mutect2, varscan2
- ZFHX4 | c.4312C>G p.Q1438E | Missense Mutation (SNP) | VAF 29/49 reads (59%) | SIFT tolerated (0.21); PolyPhen benign (0.142); catalogued as COSV99261289, COSV99261639; called by muse, mutect2, varscan2
- ZNF335 | c.304G>T p.G102C | Missense Mutation (SNP) | VAF 32/55 reads (58%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.956); catalogued as COSV100532907, COSV59816534; called by muse, mutect2, varscan2
- ZNF497 | c.471C>A p.S157R | Missense Mutation (SNP) | VAF 10/23 reads (43%) | SIFT deleterious (0); PolyPhen benign (0.261); catalogued as COSV99568307, COSV99568686; called by muse, mutect2, varscan2
- ZNF839 | c.533A>T p.Q178L (on ENST00000558850 / NM_001267827.1; = p.Q294L on NM_018335.5) | Missense Mutation (SNP) | VAF 10/25 reads (40%) | SIFT tolerated (0.08); PolyPhen benign (0.038); catalogued as COSV99216179; called by muse, mutect2, varscan2
- ZNHIT1 | c.289G>A p.E97K | Missense Mutation (SNP) | VAF 61/86 reads (71%) | SIFT tolerated (0.36); PolyPhen benign (0.007); catalogued as rs1331341810, COSV59313046; called by muse, mutect2, varscan2
- ABCA2 | c.3006del p.R1003Afs*36 (on ENST00000614293; = p.R973Afs*36 on NM_001606.5 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 13/56 reads (23%) | called by mutect2, pindel, varscan2
- ATP7A | c.3410_3411del p.I1137Rfs*4 | Frame Shift Del (DEL) | VAF 32/136 reads (24%) | called by pindel, varscan2
- FRG2C | c.571C>A p.L191I | Missense Mutation (SNP) | VAF 24/230 reads (10%) | SIFT tolerated (0.86); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- H1-8 | c.42del p.T15Lfs*83 | Frame Shift Del (DEL) | VAF 8/22 reads (36%) | called by mutect2, pindel, varscan2
- IGHV1OR21-1 | c.201G>T p.M67I | Missense Mutation (SNP) | VAF 38/336 reads (11%) | SIFT tolerated (0.98); PolyPhen benign (0.07); called by muse, mutect2
- IGHV3OR16-8 | c.82G>T p.G28* | Nonsense Mutation (SNP) | VAF 36/228 reads (16%) | called by muse, mutect2, varscan2
- IGHV3OR16-8 | c.263C>G p.T88S | Missense Mutation (SNP) | VAF 81/448 reads (18%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.346); called by muse, mutect2, varscan2
- PHKA1 | c.454+1del p.X152_splice | Splice Site (DEL) | VAF 17/71 reads (24%) | called by mutect2, pindel
- PRAMEF17 | c.1327G>C p.E443Q | Missense Mutation (SNP) | VAF 75/204 reads (37%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.95); called by muse, mutect2, varscan2
- RPH3A | c.1281G>T p.L427F (on ENST00000389385 / NM_001143854.2; = p.L423F on NM_014954.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 29/102 reads (28%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- SAGE1 | c.2517del p.Q840Kfs*17 | Frame Shift Del (DEL) | VAF 23/92 reads (25%) | called by mutect2, pindel, varscan2
- SPO11 | c.1009del p.M337* | Frame Shift Del (DEL) | VAF 37/100 reads (37%) | called by mutect2, pindel, varscan2
- TRBJ2-5 | c.6del p.E3Rfs*? | Frame Shift Del (DEL) | VAF 24/32 reads (75%) | called by mutect2, varscan2
- TRBV5-1 | c.115A>G p.T39A | Missense Mutation (SNP) | VAF 7/45 reads (16%) | SIFT tolerated (0.13); PolyPhen benign (0.219); called by mutect2, varscan2
- TRGV8 | c.316C>A p.R106S | Missense Mutation (SNP) | VAF 26/110 reads (24%) | SIFT tolerated (1); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- ABCC5 | c.3024A>T p.A1008= | Silent (SNP) | VAF 18/54 reads (33%) | catalogued as COSV55590139; called by muse, mutect2, varscan2
- AP4E1 | c.1572C>G p.L524= | Silent (SNP) | VAF 17/33 reads (52%) | catalogued as COSV99956535; called by muse, varscan2
- ARHGEF18 | c.1491C>T p.L497= (on ENST00000359920 / NM_001130955.2; = p.L393= on NM_015318.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 16/27 reads (59%) | catalogued as rs771857478, COSV100149415; called by muse, mutect2, varscan2
- ASXL3 | c.4971C>A p.P1657= | Silent (SNP) | VAF 29/60 reads (48%) | catalogued as COSV99324545; called by muse, mutect2, varscan2
- ATXN2 | c.1515C>T p.S505= (on ENST00000550104; = p.S345= on NM_002973.4) | Silent (SNP) | VAF 34/120 reads (28%) | catalogued as COSV101112714; called by muse, mutect2, varscan2
- BAG1 | c.240G>T p.S80= | Silent (SNP) | VAF 19/53 reads (36%) | catalogued as rs769742000, COSV99794556; called by muse, mutect2, varscan2
- BHMT | c.396G>A p.K132= | Silent (SNP) | VAF 22/45 reads (49%) | catalogued as rs771838936, COSV99165401; called by muse, mutect2, varscan2
- BMPER | c.1152G>T p.G384= | Silent (SNP) | VAF 32/198 reads (16%) | catalogued as COSV51818971, COSV51824044; called by muse, mutect2, varscan2
- C2orf16 | c.5298T>C p.H1766= | Silent (SNP) | VAF 87/336 reads (26%) | catalogued as rs762170440, COSV100820761; called by muse, mutect2, varscan2
- C2orf50 | c.231G>A p.E77= | Silent (SNP) | VAF 9/30 reads (30%) | catalogued as COSV101059448; called by muse, mutect2, varscan2
- CARD18 | c.198C>A p.P66= | Silent (SNP) | VAF 48/172 reads (28%) | catalogued as COSV101596028; called by muse, mutect2, varscan2
- CD226 | c.585A>T p.I195= | Silent (SNP) | VAF 26/85 reads (31%) | catalogued as COSV99711031; called by muse, mutect2, varscan2
- CHD6 | c.2595G>T p.G865= | Silent (SNP) | VAF 8/29 reads (28%) | catalogued as COSV100498107, COSV58553681; called by muse, mutect2, varscan2
- CNNM1 | c.2772C>A p.T924= | Silent (SNP) | VAF 5/22 reads (23%) | catalogued as COSV100763833; called by muse, mutect2, varscan2
- COL9A2 | c.1554G>T p.R518= | Silent (SNP) | VAF 8/18 reads (44%) | catalogued as COSV101028455; called by muse, mutect2, varscan2
- DCAF4L2 | c.405G>T p.L135= | Silent (SNP) | VAF 33/127 reads (26%) | catalogued as COSV100150767; called by muse, mutect2, varscan2
- DNAH10 | c.13245C>T p.T4415= (on ENST00000409039; = p.T4354= on NM_207437.3) | Silent (SNP) | VAF 17/61 reads (28%) | catalogued as rs1359393680, COSV99435451; called by muse, mutect2, varscan2
- DNAH7 | c.5599T>C p.L1867= | Silent (SNP) | VAF 19/40 reads (48%) | catalogued as rs149685696, COSV100414871; called by muse, mutect2, varscan2
- DRAM2 | c.411T>C p.F137= | Silent (SNP) | VAF 25/76 reads (33%) | catalogued as COSV99713386; called by muse, mutect2, varscan2
- EPPK1 | c.6510A>G p.K2170= | Silent (SNP) | VAF 43/198 reads (22%) | catalogued as COSV101599814; called by muse, mutect2, varscan2
- GALNT6 | c.63G>C p.V21= | Silent (SNP) | VAF 10/37 reads (27%) | catalogued as COSV100695411; called by muse, mutect2, varscan2
- GRIK1 | c.30C>A p.P10= | Silent (SNP) | VAF 6/25 reads (24%) | catalogued as COSV100516397; called by muse, mutect2
- GTF3C1 | c.3771G>T p.R1257= | Silent (SNP) | VAF 60/138 reads (43%) | catalogued as COSV100649304; called by muse, mutect2, varscan2
- GUCY2C | c.3183G>A p.L1061= | Silent (SNP) | VAF 36/159 reads (23%) | catalogued as COSV99663536; called by muse, mutect2, varscan2
- HCN1 | c.2391G>C p.V797= | Silent (SNP) | VAF 10/89 reads (11%) | catalogued as COSV100299842, COSV57507087; called by muse, mutect2, varscan2
- HDC | c.1443C>A p.S481= | Silent (SNP) | VAF 22/40 reads (55%) | catalogued as COSV99983959; called by muse, mutect2, varscan2
- HECW1 | c.1698G>C p.L566= | Silent (SNP) | VAF 20/108 reads (19%) | catalogued as COSV101223326, COSV67838101; called by muse, mutect2, varscan2
- HGF | c.555G>A p.G185= | Silent (SNP) | VAF 89/113 reads (79%) | catalogued as COSV99736623; called by muse, mutect2, varscan2
- HIP1 | c.1110G>A p.K370= | Silent (SNP) | VAF 78/121 reads (64%) | catalogued as rs1450659686, COSV100417391; called by muse, mutect2, varscan2
- HMGN5 | c.354A>T p.A118= | Silent (SNP) | VAF 5/14 reads (36%) | catalogued as COSV100814837; called by muse, mutect2, varscan2
- ITGA8 | c.1485G>C p.L495= | Silent (SNP) | VAF 31/117 reads (26%) | catalogued as COSV100959130, COSV65233185; called by muse, mutect2, varscan2
- KCNA1 | c.1008G>T p.G336= | Silent (SNP) | VAF 41/125 reads (33%) | catalogued as COSV101230205; called by muse, mutect2, varscan2
- KRT3 | c.1069C>T p.L357= | Silent (SNP) | VAF 11/43 reads (26%) | catalogued as COSV100527015, COSV58816027; called by muse, mutect2, varscan2
- KRT38 | c.81C>A p.P27= | Silent (SNP) | VAF 23/69 reads (33%) | catalogued as COSV99878180; called by muse, mutect2, varscan2
- LAIR2 | c.210T>C p.D70= | Silent (SNP) | VAF 36/76 reads (47%) | catalogued as rs1360811003, COSV100003242; called by muse, mutect2, varscan2
- LMAN2L | c.966G>C p.L322= | Silent (SNP) | VAF 11/34 reads (32%) | catalogued as COSV99383285; called by muse, mutect2, varscan2
- LMOD2 | c.597T>A p.I199= | Silent (SNP) | VAF 17/31 reads (55%) | catalogued as COSV101505441; called by muse, mutect2, varscan2
- LRPPRC | c.868C>T p.L290= | Silent (SNP) | VAF 10/56 reads (18%) | catalogued as rs1302741572, COSV99580446; called by muse, mutect2, varscan2
- MED1 | c.312G>T p.T104= | Silent (SNP) | VAF 37/127 reads (29%) | catalogued as COSV100327725, COSV56124384; called by muse, mutect2, varscan2
- MMP16 | c.165G>T p.P55= | Silent (SNP) | VAF 15/48 reads (31%) | catalogued as rs775243884, COSV54155167, COSV99687567; called by muse, mutect2, varscan2
- MYO1G | c.2388G>T p.R796= | Silent (SNP) | VAF 59/120 reads (49%) | catalogued as COSV99348660; called by muse, mutect2, varscan2
- NCL | c.1170A>C p.R390= | Silent (SNP) | VAF 14/42 reads (33%) | catalogued as COSV100502323; called by muse, mutect2, varscan2
- OR10G8 | c.798T>A p.A266= | Silent (SNP) | VAF 55/92 reads (60%) | catalogued as COSV101461830; called by muse, mutect2, varscan2
- OR2T35 | c.864C>A p.L288= | Silent (SNP) | VAF 12/69 reads (17%) | called by muse, mutect2, varscan2
- OR4K13 | c.99G>T p.V33= | Silent (SNP) | VAF 16/67 reads (24%) | catalogued as COSV100237715; called by muse, mutect2, varscan2
- OR52B2 | c.867G>T p.L289= | Silent (SNP) | VAF 30/51 reads (59%) | catalogued as COSV101603940; called by muse, mutect2, varscan2
- OR9G1 | c.315G>C p.G105= | Silent (SNP) | VAF 21/147 reads (14%) | catalogued as COSV100380361, COSV56454643; called by muse, mutect2, varscan2
- PCDHA1 | c.1747C>A p.R583= | Silent (SNP) | VAF 35/69 reads (51%) | catalogued as COSV100974345, COSV65375766; called by muse, mutect2, varscan2
- PCDHB13 | c.2157G>T p.A719= | Silent (SNP) | VAF 64/136 reads (47%) | catalogued as COSV53393520, COSV99507142; called by muse, mutect2, varscan2
- PCDHB3 | c.2235G>A p.L745= | Silent (SNP) | VAF 38/106 reads (36%) | catalogued as rs145557525; called by muse, mutect2, varscan2
- PDE8A | c.2235G>T p.S745= | Silent (SNP) | VAF 26/61 reads (43%) | catalogued as COSV100051776, COSV59638150; called by muse, mutect2, varscan2
- PDZD4 | c.174G>T p.G58= | Silent (SNP) | VAF 7/29 reads (24%) | catalogued as COSV99381250; called by muse, mutect2, varscan2
- PHEX | c.2244C>G p.L748= | Silent (SNP) | VAF 18/45 reads (40%) | catalogued as rs747154530, COSV101039563; called by muse, mutect2, varscan2
- PI4KA | c.1080C>T p.P360= | Silent (SNP) | VAF 13/32 reads (41%) | catalogued as COSV99745640; called by muse, mutect2, varscan2
- PIKFYVE | c.5247G>T p.G1749= | Silent (SNP) | VAF 20/34 reads (59%) | catalogued as COSV100010472; called by muse, mutect2, varscan2
- PPM1A | c.516A>G p.K172= | Silent (SNP) | VAF 26/109 reads (24%) | catalogued as rs774715909, COSV100348993; called by muse, mutect2, varscan2
- PRLHR | c.210G>T p.V70= | Silent (SNP) | VAF 22/90 reads (24%) | catalogued as COSV99492752; called by muse, mutect2, varscan2
- RANBP2 | c.6276G>T p.T2092= | Silent (SNP) | VAF 138/441 reads (31%) | catalogued as COSV51706606, COSV99311912; called by muse, mutect2, varscan2
- RBMXL2 | c.834C>A p.S278= | Silent (SNP) | VAF 18/34 reads (53%) | catalogued as COSV100182199; called by muse, mutect2, varscan2
- RFX3 | c.795G>T p.L265= | Silent (SNP) | VAF 31/90 reads (34%) | catalogued as COSV100174930; called by muse, mutect2, varscan2
- RSPRY1 | c.462A>T p.P154= | Silent (SNP) | VAF 69/141 reads (49%) | catalogued as COSV101070986; called by muse, mutect2, varscan2
- SEC14L3 | c.642C>A p.R214= | Silent (SNP) | VAF 26/77 reads (34%) | catalogued as COSV99307110; called by muse, mutect2, varscan2
- SGIP1 | c.1311C>G p.T437= | Silent (SNP) | VAF 69/251 reads (27%) | catalogued as COSV52778874, COSV99391236; called by muse, mutect2, varscan2
- SLC22A6 | c.30G>A p.V10= | Silent (SNP) | VAF 4/20 reads (20%) | catalogued as rs148086982; called by muse, varscan2
- SLC39A12 | c.564G>T p.L188= | Silent (SNP) | VAF 14/64 reads (22%) | catalogued as COSV101070027; called by muse, mutect2, varscan2
- SLITRK3 | c.2631C>A p.G877= | Silent (SNP) | VAF 32/85 reads (38%) | catalogued as COSV53853687, COSV99579058; called by muse, mutect2, varscan2
- SMG1 | c.2385A>G p.L795= | Silent (SNP) | VAF 7/12 reads (58%) | catalogued as COSV101245720; called by muse, mutect2, varscan2
- ST18 | c.360T>A p.S120= | Silent (SNP) | VAF 5/88 reads (6%) | catalogued as COSV99389270; called by muse, mutect2
- ST8SIA6 | c.1000C>T p.L334= | Silent (SNP) | VAF 73/245 reads (30%) | catalogued as COSV101112129; called by muse, mutect2, varscan2
- STK10 | c.318G>T p.L106= | Silent (SNP) | VAF 34/64 reads (53%) | catalogued as COSV99451316; called by muse, mutect2, varscan2
- TAMALIN | c.498C>A p.I166= | Silent (SNP) | VAF 29/114 reads (25%) | catalogued as COSV99531085; called by muse, mutect2, varscan2
- TGFBI | c.366G>T p.T122= | Silent (SNP) | VAF 13/31 reads (42%) | catalogued as rs749608724, COSV100526435, COSV59352674; called by muse, mutect2, varscan2
- TMEM132B | c.243C>A p.P81= | Silent (SNP) | VAF 54/164 reads (33%) | catalogued as COSV100169380; called by muse, mutect2, varscan2
- TMPRSS3 | c.496C>A p.R166= | Silent (SNP) | VAF 52/166 reads (31%) | catalogued as COSV52308126, COSV99367959; called by muse, mutect2, varscan2
- TPD52L3 | c.13A>C p.R5= | Silent (SNP) | VAF 33/112 reads (29%) | catalogued as COSV100095982; called by muse, mutect2, varscan2
- TRHDE | c.1057C>A p.R353= | Silent (SNP) | VAF 15/34 reads (44%) | catalogued as COSV53861169, COSV99670324; called by muse, mutect2, varscan2
- TRPC4AP | c.2037G>A p.Q679= | Silent (SNP) | VAF 8/12 reads (67%) | catalogued as COSV99328248; called by muse, mutect2
- TSPOAP1 | c.2814C>T p.G938= | Silent (SNP) | VAF 23/60 reads (38%) | catalogued as rs750611140, COSV99270880; called by muse, mutect2, varscan2
- WDR45 | c.633C>A p.S211= (on ENST00000376372 / NM_001029896.2; = p.S212= on NM_007075.3) | Silent (SNP) | VAF 8/43 reads (19%) | catalogued as COSV100540231; called by muse, mutect2, varscan2
- WWC3 | c.2925G>T p.A975= | Silent (SNP) | VAF 4/15 reads (27%) | catalogued as COSV101081364; called by muse, mutect2, varscan2
- XIRP1 | c.3009T>A p.P1003= | Silent (SNP) | VAF 14/39 reads (36%) | catalogued as COSV100453555; called by muse, mutect2, varscan2
- ZAN | c.6069C>T p.I2023= | Silent (SNP) | VAF 89/111 reads (80%) | catalogued as COSV61805598; called by muse, mutect2
- ZC3H12B | c.2115C>T p.S705= | Silent (SNP) | VAF 9/34 reads (26%) | catalogued as rs781174103, COSV59047805; called by muse, mutect2, varscan2
- ZC3H7A | c.138T>C p.L46= | Silent (SNP) | VAF 24/65 reads (37%) | catalogued as COSV100865500; called by muse, mutect2, varscan2
- ZCCHC12 | c.999G>T p.G333= | Silent (SNP) | VAF 33/126 reads (26%) | catalogued as COSV100038483; called by muse, mutect2, varscan2
- ZEB2 | c.1095C>T p.A365= | Silent (SNP) | VAF 22/73 reads (30%) | catalogued as COSV100355771; called by muse, mutect2, varscan2
- ZFC3H1 | c.3123A>G p.R1041= | Silent (SNP) | VAF 62/182 reads (34%) | catalogued as COSV101110483; called by muse, mutect2, varscan2
- ZNF711 | c.1014G>A p.Q338= | Silent (SNP) | VAF 21/86 reads (24%) | catalogued as rs1193507347, COSV99340946; called by muse, mutect2, varscan2
- AMOT | c.*2C>T | 3'UTR (SNP) | VAF 78/311 reads (25%) | catalogued as rs747101663, COSV100494965; called by muse, mutect2, varscan2
- C1orf220 | n.683A>T | RNA (SNP) | VAF 13/77 reads (17%) | called by muse, mutect2, varscan2
- DENND10P1 | n.986C>T | RNA (SNP) | VAF 53/171 reads (31%) | called by muse, mutect2, varscan2
- DKC1 | c.771+226A>T | Intron (SNP) | VAF 22/82 reads (27%) | catalogued as COSV101059874; called by muse, mutect2, varscan2
- RPGR | c.2520+1177G>C | Intron (SNP) | VAF 5/13 reads (38%) | called by muse, mutect2, varscan2
- SERPINA13P | n.838C>G | RNA (SNP) | VAF 30/63 reads (48%) | called by muse, mutect2, varscan2
